Somatic mutation profile of tumor specimen TCGA-43-6771-01A (aliquot TCGA-43-6771-01A-11D-1817-08) from TCGA case TCGA-43-6771, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 85.0 years (31,052 days).
Specimen TCGA-43-6771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9af5c751-b642-449d-8013-707ffd90b534.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-6771-10A (Blood Derived Normal), aliquot TCGA-43-6771-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a28fc1ad-1b44-4908-83e9-e741251b1218

The open-access MAF lists 228 somatic variants for this specimen: 173 protein-altering or splice-affecting, 47 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 47, Nonsense Mutation 11, Splice Site 5, Intron 3, Frame Shift Del 3, Splice Region 3, Nonstop Mutation 2, 3'Flank 2, RNA 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 429/567 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.879G>T p.M293I | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64677406; called by muse, mutect2, varscan2
- ABCC5 | c.1276T>A p.F426I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV55595724; called by muse, mutect2, varscan2
- ADA2 | c.1072G>C p.G358R (on ENST00000262607; = p.G117R on NM_177405.3) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52833624; called by muse, mutect2, varscan2
- ADGRB3 | c.522G>T p.W174C | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65411199; called by muse, mutect2, varscan2
- ADGRL2 | c.3136C>G p.L1046V (on ENST00000370717 / NM_001366005.1; = p.L1033V on NM_012302.4) | Missense Mutation (SNP) | VAF 67/339 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54686614; called by muse, mutect2, varscan2
- AFF4 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM152550, COSV54799305; called by muse, mutect2, varscan2
- AHNAK2 | c.2599G>A p.V867M | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs369984421; called by muse, mutect2, varscan2
- AK7 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 51/284 reads (18%) | catalogued as rs114393353, COSV50870705, COSV50881490; called by muse, mutect2, varscan2
- AMBN | c.1343G>C p.*448Sext*3 | Nonstop Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV59827963; called by muse, mutect2, varscan2
- ANK2 | c.7264A>C p.S2422R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52185485; called by muse, mutect2, varscan2
- ANKRD12 | c.4440G>T p.Q1480H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV50845034; called by muse, mutect2, varscan2
- ANKRD12 | c.4441G>T p.D1481Y | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV50829548, COSV50845122; called by muse, mutect2, varscan2
- AP002512.3 | c.973G>T p.V325L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.26); catalogued as COSV54408614; called by muse, mutect2
- ATP2B2 | c.1924C>T p.R642W (on ENST00000352432; = p.R608W on NM_001683.5) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs544333948, COSV59506516; called by muse, mutect2, varscan2
- BEST3 | c.1697C>A p.T566K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV58305165; called by muse, mutect2, varscan2
- BIRC6 | c.10918G>T p.A3640S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.096); catalogued as COSV70205008, COSV70205082; called by muse, mutect2, varscan2
- BIRC6 | c.11821A>T p.R3941W | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV70205016; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.477A>T p.S159= | Splice Region (SNP) | VAF 7/40 reads (18%) | catalogued as COSV57282334; called by muse, mutect2, varscan2
- BMPER | c.1829A>C p.Q610P | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.366); catalogued as COSV51830062; called by muse, mutect2, varscan2
- BRINP3 | c.760C>A p.R254S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66539622; called by muse, mutect2, varscan2
- C10orf88 | c.488T>G p.V163G | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64404384; called by muse, mutect2, varscan2
- C16orf90 | c.233T>A p.L78Q (on ENST00000399645 / NM_001353385.2; = p.L69Q on NM_001080524.2) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV68714646; called by muse, mutect2, varscan2
- CACNA2D1 | c.982A>G p.K328E | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as COSV62391049; called by muse, mutect2, varscan2
- CASP5 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as COSV52831475; called by muse, mutect2, varscan2
- CCDC33 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58357269; called by muse, mutect2, varscan2
- CCDC63 | c.1280A>G p.K427R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57530641; called by muse, mutect2, varscan2
- CCN3 | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52385163; called by muse, mutect2, varscan2
- CCT8L2 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV63463693; called by muse, mutect2, varscan2
- CD4 | c.477G>T p.R159S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99163841; called by muse, mutect2, varscan2
- CEACAM18 | c.314C>A p.T105N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as COSV67283988; called by muse, mutect2, varscan2
- CHD5 | c.3526G>T p.G1176C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99314331; called by muse, mutect2, varscan2
- CHRNB2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.916); catalogued as rs201622476, COSV63808315; called by muse, mutect2, varscan2
- CLDN1 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55044071, COSV55045100; called by muse, mutect2, varscan2
- CLSTN2 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV71724573; called by muse, mutect2, varscan2
- CNR2 | c.33T>A p.N11K | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV65694421; called by muse, mutect2, varscan2
- COL20A1 | c.2126G>C p.R709T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.173); catalogued as COSV58926410; called by muse, mutect2, varscan2
- COQ8B | c.1169G>T p.S390I | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV54688818; called by muse, varscan2
- CPA3 | c.474+1G>T p.X158_splice | Splice Site (SNP) | VAF 28/102 reads (27%) | catalogued as rs776955071, COSV56047149, COSV99935950; called by muse, varscan2
- CUBN | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as COSV64726119; called by muse, mutect2, varscan2
- DACH1 | c.2240-1G>T p.X747_splice (on ENST00000619232 / NM_001366712.1; = p.X493_splice on NM_004392.6) | Splice Site (SNP) | VAF 30/137 reads (22%) | catalogued as COSV100498799; called by muse, mutect2, varscan2
- DAO | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57324377; called by muse, mutect2, varscan2
- DBF4B | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV59263347; called by muse, mutect2, varscan2
- DCT | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.531); catalogued as rs1373906882, COSV65470603; called by muse, mutect2, varscan2
- DEF6 | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV57355298; called by muse, mutect2, varscan2
- DLGAP5 | c.1546C>A p.Q516K | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55965095; called by muse, mutect2, varscan2
- DNAH2 | c.6502G>C p.G2168R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66726179; called by muse, mutect2, varscan2
- DOCK5 | c.3902A>G p.Y1301C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52399833; called by muse, mutect2, varscan2
- DRC7 | c.2334C>A p.S778R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV61057635; called by muse, mutect2, varscan2
- DRD3 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55682655; called by muse, mutect2, varscan2
- DSEL | c.3327G>T p.L1109F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59494317; called by muse, mutect2, varscan2
- EFCAB3 | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV59504614; called by muse, mutect2, varscan2
- EPHA8 | c.2565C>A p.Y855* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as COSV51293844; called by muse, mutect2, varscan2
- ERBIN | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52326248; called by muse, mutect2, varscan2
- ERVFRD-1 | c.509C>A p.P170Q | Missense Mutation (SNP) | VAF 147/359 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.31); catalogued as rs1391832979, COSV100977409; called by muse, mutect2, varscan2
- FAM71B | c.1145C>A p.T382N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV57230715, COSV57231180; called by muse, mutect2
- FAM71B | c.875C>A p.A292E | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1239552054, COSV57230730; called by muse, mutect2, varscan2
- FBLN2 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as rs754715705, COSV55487963, COSV55490379; called by muse, mutect2, varscan2
- FBN1 | c.3644C>G p.S1215C | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV57328817; called by muse, mutect2, varscan2
- FER1L6 | c.4009G>C p.E1337Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.205); catalogued as rs1345877284, COSV67552560; called by muse, mutect2, varscan2
- GABRE | c.217C>G p.R73G | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV64818761, COSV64819994, COSV64821147; called by muse, mutect2, varscan2
- GALNT1 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.029); catalogued as COSV52454768, COSV99321734; called by muse, mutect2, varscan2
- GLT8D2 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.332); catalogued as COSV62562948; called by muse, mutect2, varscan2
- GPR1 | c.1058C>G p.T353R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV67977440; called by muse, mutect2, varscan2
- HADHB | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.546); catalogued as rs987203346, COSV58548462; called by muse, mutect2, varscan2
- HSF5 | c.1719T>C p.P573= | Splice Region (SNP) | VAF 14/59 reads (24%) | catalogued as COSV60419311; called by muse, mutect2, varscan2
- ILK | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV54990736; called by muse, mutect2, varscan2
- ILK | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV54992108; called by muse, mutect2, varscan2
- INPP4A | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs1465343631, COSV50827322; called by muse, mutect2, varscan2
- IRGQ | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60671430; called by muse, mutect2, varscan2
- ITPRID1 | c.1119G>C p.K373N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV60081891; called by muse, mutect2, varscan2
- KCNG4 | c.123C>A p.Y41* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as rs371009755; called by muse, mutect2, varscan2
- KCNK9 | c.667T>A p.F223I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57287798; called by muse, mutect2, varscan2
- KIF4B | c.3623C>T p.P1208L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV70531150; called by muse, mutect2, varscan2
- KIFBP | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV62556754; called by muse, mutect2, varscan2
- KIR3DL3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1277875430, COSV52550084; called by muse, mutect2, varscan2
- KLHL11 | c.778G>C p.V260L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV59863032; called by muse, mutect2, varscan2
- KNTC1 | c.5903G>A p.C1968Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61083674; called by muse, mutect2, varscan2
- KPNA5 | c.752G>T p.S251I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV62654432; called by muse, mutect2, varscan2
- KRT38 | c.492+1G>A p.X164_splice | Splice Site (SNP) | VAF 24/111 reads (22%) | catalogued as rs1231293903, COSV99878291; called by muse, mutect2, varscan2
- KRTAP11-1 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.991); catalogued as COSV60095322; called by muse, mutect2, varscan2
- LCE5A | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.018); catalogued as COSV57500342, COSV57501502; called by muse, mutect2
- LRP1B | c.3556C>A p.H1186N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1170996968, COSV67269568; called by muse, mutect2, varscan2
- LRP1B | c.3352G>A p.G1118R | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67269573; called by muse, mutect2, varscan2
- LRP1B | c.2437C>A p.P813T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV67269576; called by muse, mutect2, varscan2
- LRP5 | c.3905A>T p.Q1302L | Missense Mutation (SNP) | VAF 300/435 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV53723007; called by muse, mutect2, varscan2
- LRRC3B | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV67522555; called by muse, mutect2, varscan2
- LRRC4C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1323279700, COSV53423393; called by muse, mutect2, varscan2
- MAPK10 | c.803G>T p.G268V (on ENST00000359221 / NM_001351625.2; = p.G306V on NM_002753.5) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV60392825; called by muse, mutect2, varscan2
- MARK1 | c.1470+1G>C p.X490_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV65070950; called by muse, mutect2, varscan2
- MEGF8 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs972539405, COSV52099788; called by muse, mutect2, varscan2
- MPEG1 | c.1566C>A p.S522R | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV57094617; called by muse, mutect2, varscan2
- MRGPRE | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as rs1191038485, COSV67745963; called by muse, mutect2, varscan2
- MTMR12 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 40/152 reads (26%) | catalogued as COSV53787622; called by muse, mutect2, varscan2
- MTOR | c.5287G>T p.G1763C | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63877679; called by muse, mutect2, varscan2
- MTOR | c.5286G>C p.Q1762H | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.353); catalogued as COSV63877683; called by muse, mutect2, varscan2
- MUTYH | c.1416G>T p.W472C | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58343680, COSV58344935; called by muse, mutect2, varscan2
- MXRA5 | c.935A>T p.Q312L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV54248608; called by muse, mutect2, varscan2
- MYH7 | c.3652G>T p.E1218* | Nonsense Mutation (SNP) | VAF 19/129 reads (15%) | catalogued as CM031280, COSV100806358; called by muse, mutect2, varscan2
- NCOR1 | c.3242C>T p.P1081L | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs1237541182, COSV51994234; called by muse, mutect2, varscan2
- NCOR2 | c.3450G>T p.M1150I | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV62302408, COSV62303702; called by muse, mutect2
- NCOR2 | c.3448A>T p.M1150L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.811); catalogued as COSV62303713; called by muse, mutect2
- NDST1 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55790566, COSV99938845; called by muse, mutect2, varscan2
- NKD1 | c.774C>G p.H258Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51694094; called by muse, mutect2, varscan2
- NLRP9 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV60467376; called by muse, mutect2, varscan2
- NOS1 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs760365815, COSV57620407; called by muse, mutect2, varscan2
- NRXN1 | c.4363G>T p.E1455* | Nonsense Mutation (SNP) | VAF 26/105 reads (25%) | catalogued as COSV60520265; called by muse, mutect2, varscan2
- NUP62 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV61312703; called by muse, mutect2, varscan2
- OIT3 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs149032084; called by muse, mutect2, varscan2
- OR1D5 | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV73859639; called by muse, mutect2, varscan2
- OR2A5 | c.313A>G p.M105V | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs758511312, COSV68739089; called by muse, mutect2, varscan2
- OR2L13 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV63560079; called by muse, mutect2, varscan2
- OR2T1 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV100822337; called by muse, mutect2, varscan2
- OR2T5 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.15); catalogued as rs753698718, COSV63540663; called by mutect2, varscan2
- OR4C46 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.56); catalogued as rs554155145, COSV60221080; called by muse, mutect2, varscan2
- OR4S2 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 49/83 reads (59%) | catalogued as COSV56748245; called by muse, mutect2, varscan2
- OR51V1 | c.598T>A p.Y200N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV58316264; called by muse, mutect2, varscan2
- OR52E8 | c.216G>T p.L72F | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs747160460, COSV66211827; called by muse, varscan2
- OR5AP2 | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57258708; called by muse, mutect2, varscan2
- OR9G4 | c.796T>C p.Y266H | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV57249739; called by muse, mutect2, varscan2
- PADI2 | c.584C>A p.P195H | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100971021; called by muse, mutect2, varscan2
- PCDHGA11 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.219); catalogued as COSV54021659; called by muse, mutect2, varscan2
- PCDHGA2 | c.1717A>T p.T573S | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV54021636; called by muse, mutect2, varscan2
- PDZD2 | c.8339A>G p.K2780R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56871308; called by muse, mutect2, varscan2
- PHC3 | c.956A>C p.K319T (on ENST00000494943 / NM_001308116.2; = p.K331T on NM_024947.4) | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1182518498, COSV71949300; called by muse, mutect2, varscan2
- PHF24 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54276604; called by muse, mutect2, varscan2
- PITHD1 | c.636A>T p.*212Yext*13 | Nonstop Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV55755729; called by muse, mutect2, varscan2
- POLQ | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV51760361; called by muse, mutect2, varscan2
- POT1 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62933692; called by muse, mutect2, varscan2
- PPFIA1 | c.1922A>T p.K641I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV54140267; called by muse, mutect2, varscan2
- PRR5 | c.1112G>T p.R371L (on ENST00000336985 / NM_181333.4; = p.R362L on NM_015366.4) | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.044); catalogued as COSV50061043; called by muse, mutect2, varscan2
- PSG9 | c.914C>A p.T305K | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV52488164; called by muse, mutect2, varscan2
- PZP | c.983-1G>A p.X328_splice | Splice Site (SNP) | VAF 17/55 reads (31%) | catalogued as COSV54369294; called by muse, mutect2, varscan2
- RASAL3 | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59141484; called by muse, mutect2, varscan2
- RENBP | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64170555; called by muse, mutect2, varscan2
- RFX6 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.205); catalogued as COSV60588397; called by muse, mutect2, varscan2
- RTL9 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV71826262; called by muse, mutect2, varscan2
- RYR1 | c.3580G>T p.G1194* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV62109458; called by muse, mutect2, varscan2
- RYR2 | c.6850G>T p.G2284C | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1358347233, COSV63710725; called by muse, mutect2, varscan2
- SERPINA5 | c.1097C>A p.T366K | Missense Mutation (SNP) | VAF 126/429 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV61574967; called by muse, mutect2
- SESN2 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53429021; called by muse, mutect2
- SESN2 | c.1078G>T p.G360W | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99455926; called by muse, mutect2
- SIGLEC5 | c.900G>C p.E300D | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.372); catalogued as COSV55783570; called by muse, mutect2, varscan2
- SLC27A1 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV53100472; called by muse, mutect2, varscan2
- SLC4A10 | c.1505G>A p.R502K (on ENST00000446997 / NM_001354461.2; = p.R472K on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1198476375, COSV55797795; called by muse, mutect2, varscan2
- SLIT3 | c.1207C>G p.Q403E | Missense Mutation (SNP) | VAF 75/309 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV60631108; called by muse, mutect2, varscan2
- SLITRK1 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.281); catalogued as COSV65677398; called by muse, mutect2, varscan2
- SMC1B | c.301G>T p.G101* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV62533075; called by muse, mutect2
- SMC1B | c.300G>T p.G100= | Splice Region (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100663383; called by muse, mutect2
- SOX8 | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV53510566; called by muse, mutect2, varscan2
- SP1 | c.964A>T p.T322S (on ENST00000327443 / NM_138473.3; = p.T315S on NM_003109.1) | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV59405037; called by muse, mutect2, varscan2
- STK40 | c.494A>T p.K165M | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV63736858; called by muse, mutect2, varscan2
- SYNGAP1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV53386270; called by muse, varscan2
- TAOK1 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as rs1384657982, COSV55594722, COSV55598126; called by muse, mutect2, varscan2
- TBX2 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs768834035, COSV53600957; called by muse, mutect2, varscan2
- TTC37 | c.2780C>T p.T927I | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV62456671; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4200G>T p.Q1400H | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV54442197; called by muse, mutect2, varscan2
- USP19 | c.3826C>T p.P1276S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.015); catalogued as COSV60276061; called by muse, mutect2
- ZEB2 | c.2224C>A p.P742T | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV57956887; called by muse, varscan2
- ZFP64 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1360484121, COSV53798925, COSV53803475, COSV99402108; called by muse, mutect2, varscan2
- ZFYVE9 | c.612A>T p.E204D | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV55099204; called by muse, mutect2, varscan2
- ZIC1 | c.492G>T p.R164S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV51557486; called by muse, mutect2, varscan2
- ZIC1 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51557494; called by muse, mutect2, varscan2
- ZIC4 | c.333C>A p.H111Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV67172067, COSV67173976; called by muse, mutect2, varscan2
- ZMYM5 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV61989814; called by muse, mutect2, varscan2
- ZNF239 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60019611; called by muse, mutect2, varscan2
- ZNF536 | c.3461G>T p.S1154I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as COSV62833174; called by muse, mutect2, varscan2
- ZNF626 | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555771903, COSV52482657; called by muse, mutect2, varscan2
- ZPLD1 | c.755T>A p.F252Y (on ENST00000466937 / NM_001329788.1; = p.F268Y on NM_175056.2) | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60355900; called by muse, mutect2, varscan2
- OR4K2 | c.24del p.M9Cfs*37 | Frame Shift Del (DEL) | VAF 44/413 reads (11%) | called by mutect2, pindel, varscan2
- RANBP3L | c.414del p.V139* | Frame Shift Del (DEL) | VAF 43/163 reads (26%) | called by mutect2, pindel, varscan2
- SYNRG | c.2237A>T p.D746V | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.12358del p.R4120Afs*11 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- ADA2 | c.1071C>T p.A357= (on ENST00000262607; = p.A116= on NM_177405.3) | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs144447953, COSV52831065; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRG7 | c.1899C>A p.T633= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs761227434, COSV56300828; called by muse, mutect2, varscan2
- AFF4 | c.762T>G p.T254= | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as COSV54799291; called by muse, mutect2, varscan2
- AKAP13 | c.5706C>T p.S1902= (on ENST00000394518 / NM_007200.5; = p.S1906= on NM_006738.6) | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV63468577; called by muse, varscan2
- AMER3 | c.336G>T p.V112= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100366736; called by muse, mutect2, varscan2
- ANTXR2 | c.252G>A p.V84= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs886059657, COSV55020645; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AOPEP | c.84G>T p.L28= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV52923335; called by muse, mutect2, varscan2
- APBA2 | c.1506T>C p.H502= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs374089842; called by muse, mutect2, varscan2
- ARHGEF12 | c.3069A>G p.E1023= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV63107111; called by muse, mutect2, varscan2
- C10orf88 | c.489G>T p.V163= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV64404377; called by muse, mutect2, varscan2
- CALCRL | c.1311T>A p.P437= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV66477202; called by muse, varscan2
- CAPSL | c.27A>T p.R9= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV68439343; called by muse, mutect2, varscan2
- CFAP161 | c.564C>T p.S188= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as COSV54430361; called by muse, mutect2, varscan2
- CLEC18C | c.1290C>T p.Y430= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs775126405, COSV58501008; called by muse, mutect2, varscan2
- CNTNAP5 | c.1500C>A p.S500= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV70509702; called by muse, mutect2, varscan2
- COMMD10 | c.608G>A p.*203= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as COSV57240509, COSV99174496; called by muse, mutect2, varscan2
- DSG4 | c.1701G>T p.L567= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV57397081; called by muse, mutect2, varscan2
- ENTPD6 | c.1140T>C p.Y380= | Silent (SNP) | VAF 57/162 reads (35%) | catalogued as COSV61752362; called by muse, mutect2, varscan2
- ERGIC1 | c.441G>T p.T147= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV67126295, COSV67129242; called by muse, mutect2, varscan2
- FAM117B | c.1308G>T p.L436= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV57421906; called by muse, mutect2, varscan2
- FAM71B | c.1143G>C p.T381= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV57230725; called by muse, mutect2
- HPSE2 | c.1021C>A p.R341= | Silent (SNP) | VAF 50/255 reads (20%) | catalogued as COSV100986028; called by muse, mutect2, varscan2
- IGHD | c.858C>A p.P286= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101162974; called by muse, mutect2, varscan2
- INSYN2A | c.930G>C p.P310= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as COSV54757887; called by muse, mutect2, varscan2
- KCNJ9 | c.465C>A p.G155= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV63632411; called by muse, varscan2
- MAGEB10 | c.45C>A p.R15= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV63311302, COSV63312588; called by muse, mutect2, varscan2
- MUC6 | c.3579C>T p.C1193= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs374090660; called by muse, mutect2, varscan2
- NCKAP1L | c.570G>T p.L190= | Silent (SNP) | VAF 41/288 reads (14%) | catalogued as COSV53211834; called by muse, mutect2, varscan2
- NES | c.4023C>A p.G1341= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as rs939672467, COSV63962724; called by muse, mutect2, varscan2
- OR10A3 | c.933A>G p.L311= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV62460142; called by muse, mutect2, varscan2
- OR2M2 | c.849C>T p.P283= | Silent (SNP) | VAF 43/192 reads (22%) | catalogued as COSV62898787, COSV62899319; called by muse, mutect2, varscan2
- OR8J3 | c.351G>T p.V117= | Silent (SNP) | VAF 77/199 reads (39%) | catalogued as COSV56883992; called by muse, mutect2, varscan2
- PADI2 | c.585C>A p.P195= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100970998, COSV64945612; called by muse, mutect2, varscan2
- PCDHA7 | c.1284G>T p.R428= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as COSV65346700; called by muse, mutect2, varscan2
- PCDHGA12 | c.2079G>C p.L693= | Silent (SNP) | VAF 35/194 reads (18%) | catalogued as COSV52766440; called by muse, mutect2, varscan2
- PCDHGB7 | c.1647C>T p.R549= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs527369615, COSV54021650; called by muse, mutect2, varscan2
- PNLIPRP2 | c.654G>T p.V218= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV53946469; called by muse, mutect2, varscan2
- PPFIA4 | c.1281G>T p.L427= (on ENST00000447715; = p.L423= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV99690760; called by muse, mutect2, varscan2
- RIPK4 | c.1305G>T p.L435= (on ENST00000352483; = p.L387= on NM_020639.3) | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV60187832, COSV60190795; called by muse, mutect2, varscan2
- ROBO2 | c.267C>A p.S89= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV59935484; called by muse, mutect2, varscan2
- RP1L1 | c.6705G>A p.G2235= | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as COSV66759692; called by muse, mutect2, varscan2
- SLC7A7 | c.1455C>A p.V485= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as COSV53538249; called by muse, mutect2, varscan2
- SLITRK5 | c.213C>A p.I71= | Silent (SNP) | VAF 63/248 reads (25%) | catalogued as COSV61523085, COSV61525872; called by muse, mutect2, varscan2
- TAFA5 | c.153C>T p.D51= (on ENST00000402357 / NM_001082967.3; = p.D44= on NM_015381.7) | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs1386191874, COSV60976847, COSV60992706; called by muse, mutect2, varscan2
- TAS1R2 | c.750G>A p.T250= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs146100319; called by mutect2, varscan2
- VWF | c.3336C>A p.A1112= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV54632826; called by muse, mutect2, varscan2
- ZFP14 | c.21A>T p.T7= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV54204577; called by muse, mutect2, varscan2
- B4GALNT1 | c.*2693G>T | 3'UTR (SNP) | VAF 33/195 reads (17%) | catalogued as COSV57544654; called by muse, mutect2, varscan2
- CASP7 | c.-64del | 5'UTR (DEL) | VAF 15/78 reads (19%) | called by mutect2, pindel, varscan2
- DIRC1 | n.318C>A | RNA (SNP) | VAF 20/95 reads (21%) | catalogued as COSV57369784; called by muse, mutect2, varscan2
- DUSP4 | c.433+4469G>T | Intron (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99529939; called by muse, mutect2, varscan2
- FLAD1 | c.1555-145A>G | Intron (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99422776; called by muse, mutect2, varscan2
- KRT18P23 | chr22:44570551 T>A | 3'Flank (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- ODF2L | chr1:86348871 T>C | 3'Flank (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99644510; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12780G>T | Intron (SNP) | VAF 27/78 reads (35%) | catalogued as COSV67448889; called by muse, mutect2, varscan2
